FM case AD6868 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Anus and anal canal.
https://portal.gdc.cancer.gov/cases/1ec6735c-94af-4577-bac4-efeba30dcad2

Female, 69.6 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the anus; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
